TCGA case TCGA-OE-A75W — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Saint Mary's Health Care. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a60e87e-6bc1-4ae0-9ccb-4cdc3e99c608

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 267 days.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.2; Tissue or organ of origin: Tail of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 75.8 years (27,684 days); Year of diagnosis: 2013; Method of diagnosis: Cytology; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 267 days; Sites of involvement: Pancreas Tail; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 22; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Days to treatment start: 87 days; Days to treatment end: 87 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 118 days; Days to treatment end: 153 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 118 days; Days to treatment end: 153 days; Treatment dose: 4,500 cGy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 118 days; Days to treatment end: 153 days; Treatment dose: 4,500 cGy; Treatment outcome: Progressive Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Distal Pancreatectomy.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 76.2 years (27,830 days); Days to diagnosis: 146 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (2 entries)
- Day 146 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 146 days; Evidence of progression type: Positive Biomarker(s).
- Follow-up contacts recording only the day: day 110, day 267.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Chronic Pancreatitis; Days to comorbidity: -30 days; Days to risk factor: -30 days; Risk factors: Chronic Pancreatitis.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Risk factors: Diabetes, NOS.

Exposures
- Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Alcohol drinks per day: 3; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1956; Tobacco smoking quit year: 1976.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OE-A75W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-OE-A75W-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 35; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-OE-A75W-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-OE-A75W-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Tobacco smoking history indicator: 3; Alcohol exposure intensity: Daily Drinker; Alcohol consumption frequency: 7; Diabetes diagnosis indicator: Yes; History chronic pancreatitis: Yes.
- Follow-up form: Lost to follow-up: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Gemzar.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-FU; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 267 days; disease-specific survival: event status not recorded, 267 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 146 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OE-A75W-01A-12D-A32M-01): tumor purity 0.58, ploidy 1.77, whole-genome doublings 0.
